TARGET case TARGET-40-0A4I3W — Osteosarcoma (TARGET-OS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Osseous and Chondromatous Neoplasms; Primary site: Bones, joints and articular cartilage of limbs. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8e9bb9dc-d800-55e9-bbc7-71454a4526d6

Demographics
Sex at birth: male; Race: american indian or alaska native; Age at index: 19 years; Vital status: Dead; Days to death: 1,637 days (4.5 years).

Diagnoses (1)
1. Osteosarcoma, NOS: ICD-O-3 morphology code: 9180/3; ICD-10 code: C40.2; Tissue or organ of origin: Long bones of lower limb and associated joints; Classification of tumor: primary; Age at diagnosis: 19.2 years (7,023 days); Year of diagnosis: 2007; Metastasis at diagnosis: No Metastasis; Days to last follow up: 1,637 days (4.5 years).
   Pathology details: Necrosis percent: 10.
   Treatment given: Protocol identifier: IHRT.
   Treatment given: Therapeutic agents: Doxorubicin.
   Treatment given: Therapeutic agents: Etoposide.
   Treatment given: Therapeutic agents: Ifosfamide.
   Treatment given: Therapeutic agents: Methotrexate.
   Treatment given: Therapeutic agents: Platinum.

Follow-up (2 entries)
- Days to follow up: 428 days (1.2 years); Progression or recurrence: Yes; Days to progression: 428 days (1.2 years); Days to first event: 428 days (1.2 years); First event: Relapse.
- Days to follow up: 1,637 days (4.5 years); Progression or recurrence: Yes; Progression or recurrence type: Local; Year of follow up: 2011.

Biospecimens (2 samples)
- Sample TARGET-40-0A4I3W-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-40-0A4I3W-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Validation_20230329.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 1637
- Disease at diagnosis: Non-metastatic (confirmed)
- Primary tumor site: Leg/foot
- Specific tumor site: Femur
- Specific tumor region: Distal
- Definitive Surgery: Limb sparing
- Primary site progression: Yes
- Histologic response: Stage 1/2 (0-90 % necrosis)
- Relapse Type: Locally recurrent
- Therapy: Pre-op Adria/Plat/MTX + Post-op VP-16/Ifos
